Somatic mutation profile of tumor specimen MP2PRT-PASZFM-TMP1-A (aliquot MP2PRT-PASZFM-TMP1-A-1-0-D-A835-36) from MP2PRT case MP2PRT-PASZFM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,032 days).
Specimen MP2PRT-PASZFM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89e41ce5-a4f7-41ca-90c7-28876c4ae4af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASZFM-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASZFM-NM1-A-1-0-D-A835-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d81b90b1-2231-40b6-9198-bb969ede5fce

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR8B8 | c.791C>A p.S264Y | Missense Mutation (SNP) | VAF 43/436 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV60145191; called by muse, mutect2
- DMBT1 | c.2528C>G p.P843R | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- SPEN | c.3154dup p.I1052Nfs*7 | Frame Shift Ins (INS) | VAF 174/378 reads (46%) | called by mutect2, varscan2
- SIPA1L3 | c.5106C>T p.T1702= | Silent (SNP) | VAF 147/332 reads (44%) | catalogued as COSV55908932; called by muse, mutect2, varscan2
- ZNF385D | c.288G>A p.A96= | Silent (SNP) | VAF 90/224 reads (40%) | catalogued as rs775721433, COSV55756765; called by muse, varscan2
